Somatic mutation profile of tumor specimen TCGA-A5-A0GV-01A (aliquot TCGA-A5-A0GV-01A-31W-A062-09) from TCGA case TCGA-A5-A0GV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 67.2 years (24,540 days).
Specimen TCGA-A5-A0GV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ec3f234-38a6-4bdf-ae04-fa7e390c1294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GV-10A (Blood Derived Normal), aliquot TCGA-A5-A0GV-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e34b96a5-092a-45ef-9d62-1b22741b39a4

The open-access MAF lists 52 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 4, In Frame Del 2, Intron 1, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 32/60 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1689_1709del p.M563_L570delinsI (on ENST00000521381 / NM_181523.3; = p.M293_L300delinsI on NM_181504.4) | In Frame Del (DEL) | VAF 23/97 reads (24%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 86/284 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.176A>C p.Q59P | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV60623478; called by muse, mutect2, varscan2
- ADRA1A | c.802A>T p.K268* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV52361942; called by muse, mutect2, varscan2
- CACNA1C | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs769236083, COSV59710215; called by muse, mutect2, varscan2
- CNTNAP5 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); catalogued as rs1172484897, COSV101443186, COSV70482372; called by muse, mutect2, varscan2
- DIS3L2 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 416/645 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs985913473, COSV56052519; called by muse, mutect2, varscan2
- GRM1 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV51130349, COSV51258810; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1927C>G p.R643G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100079672, COSV57131947; called by muse, mutect2, varscan2
- KL | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 88/162 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66308518; called by muse, varscan2
- MAGEB6B | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.8); catalogued as rs770913834, COSV69689543; called by muse, mutect2, varscan2
- MAN2C1 | c.3100G>A p.V1034M | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs767342082, COSV51227802; called by muse, mutect2, varscan2
- MDGA2 | c.2107G>T p.E703* (on ENST00000399232 / NM_001113498.2; = p.E405* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 37/80 reads (46%) | catalogued as rs866183737, COSV62087293; called by muse, mutect2, varscan2
- MN1 | c.2540C>G p.T847S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV56557692; called by muse, mutect2
- MNDA | c.683C>A p.P228Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV63740552; called by muse, mutect2, varscan2
- MUC16 | c.43162G>A p.G14388R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.832); catalogued as rs752728881, COSV66691254, COSV66695162; called by muse, mutect2, varscan2
- MYO1B | c.1046G>C p.R349P | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100270041, COSV58429880; called by muse, mutect2, varscan2
- MYOCD | c.946C>A p.L316I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58501971; called by muse, mutect2
- MYSM1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.311); catalogued as rs1462070962, COSV101284029, COSV68977331; called by muse, mutect2, varscan2
- PCDHA9 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs572249977, COSV65324558; called by muse, mutect2, varscan2
- PDZRN4 | c.962A>G p.Y321C (on ENST00000402685 / NM_001164595.2; = p.Y63C on NM_013377.4) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.339); catalogued as COSV54198418; called by muse, mutect2, varscan2
- PKD2 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 41/101 reads (41%) | catalogued as CD972401, CM1412759, COSV52937829; called by muse, mutect2, varscan2
- PRPF8 | c.5494C>T p.R1832C | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59262553; called by muse, mutect2, varscan2
- PTEN | c.1013_1026+4del p.X338_splice | Splice Site (DEL) | VAF 97/213 reads (46%) | catalogued as COSV64294906; called by mutect2, pindel, varscan2
- RNF31 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV53759171; called by muse, mutect2, varscan2
- SECISBP2 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 130/274 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.819); catalogued as COSV60527486, COSV60528240; called by muse, mutect2, varscan2
- SNRNP27 | c.422T>G p.M141R | Missense Mutation (SNP) | VAF 111/185 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV54911435; called by muse, mutect2, varscan2
- SPEG | c.2490C>G p.Y830* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV56667094; called by muse, mutect2, varscan2
- SPTA1 | c.5927G>T p.S1976I | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV63751792; called by muse, mutect2, varscan2
- TP73 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202137544; called by muse, mutect2, varscan2
- TTN | c.61649A>G p.Y20550C (on ENST00000591111; = p.Y13126C on NM_003319.4) | Missense Mutation (SNP) | VAF 17/24 reads (71%) | PolyPhen probably damaging (0.999); catalogued as COSV59994439; called by muse, mutect2, varscan2
- TYW5 | c.682T>C p.F228L | Missense Mutation (SNP) | VAF 121/181 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63562141; called by muse, mutect2, varscan2
- VIT | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV64895619, COSV64896227; called by muse, mutect2, varscan2
- ZNF449 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as rs138787183, COSV100203023, COSV59346763; called by muse, mutect2, varscan2
- ZZEF1 | c.3827G>A p.S1276N | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV67557079; called by muse, mutect2
- PRRC2C | c.6335_6336del p.K2112Rfs*16 (on ENST00000367742; = p.K2110Rfs*16 on NM_015172.4) | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- SGK1 | c.552_554del p.L184del | In Frame Del (DEL) | VAF 25/48 reads (52%) | called by pindel, varscan2
- ZFHX3 | c.8970dup p.Q2991Sfs*30 | Frame Shift Ins (INS) | VAF 29/77 reads (38%) | called by mutect2, pindel, varscan2
- ACSL4 | c.1035G>A p.P345= (on ENST00000340800 / NM_022977.2; = p.P304= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/131 reads (8%) | catalogued as rs1409803653, COSV61614030; called by muse, mutect2
- ACSM1 | c.1236A>G p.T412= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as COSV54634836; called by muse, mutect2, varscan2
- ATP1A3 | c.1833C>T p.S611= (on ENST00000545399 / NM_001256214.2; = p.S598= on NM_152296.5) | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs782409824, COSV57486854; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCN2 | c.648C>T p.G216= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV63466629; called by muse, mutect2, varscan2
- DAGLA | c.1140G>A p.T380= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs201855852; called by muse, mutect2
- ECT2 | c.2121G>A p.R707= (on ENST00000392692 / NM_001349098.2; = p.R676= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV51688028; called by muse, mutect2, varscan2
- HK1 | c.1827G>A p.T609= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as rs148999865, COSV53854896; called by muse, mutect2, varscan2
- L1CAM | c.2484C>T p.A828= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV62827737; called by muse, mutect2, varscan2
- LYRM9 | c.138T>C p.V46= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV66958866; called by muse, mutect2, varscan2
- PRPS2 | c.627C>T p.G209= | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as rs371983873, COSV66179421; called by muse, mutect2, varscan2
- TMED4 | c.528C>T p.Y176= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV56941766; called by muse, mutect2, varscan2
- TMEM260 | c.2080C>T p.L694= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as COSV55098319; called by muse, mutect2, varscan2
- BCAN | c.1942+24G>T | Intron (SNP) | VAF 42/160 reads (26%) | catalogued as COSV61256454; called by muse, mutect2, varscan2
